Somatic mutation profile of tumor specimen 0DSHT1 from CCDI case PBCGRJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Cervix uteri; Age at diagnosis: 14.0 years (5,104 days).
Specimen 0DSHT1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78dd5f0e-fe30-4981-8a94-c1823c25d94d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSHTA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e81340c-863a-4c6d-bb18-f2feb6a2ed07

The open-access MAF lists 93 somatic variants for this specimen: 66 protein-altering or splice-affecting, 19 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 19, Intron 4, Nonsense Mutation 3, 3'UTR 2, 5'UTR 2, Frame Shift Ins 1, In Frame Del 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.2830C>T p.R944* | Nonsense Mutation (SNP) | VAF 97/266 reads (36%) | catalogued as rs137852978, CM093994, COSV58625551; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CDH8 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 14/468 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs866885849, COSV54875153, COSV54900535; called by muse, mutect2
- COL20A1 | c.721C>G p.Q241E | Missense Mutation (SNP) | VAF 31/311 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs759945761; called by muse, mutect2, varscan2
- DICER1 | c.5113G>A p.E1705K | Missense Mutation (SNP) | VAF 88/156 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58615252, COSV58618257; called by muse, mutect2, varscan2
- DNAJB13 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 16/498 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1241364131; called by muse, mutect2
- DYRK1A | c.1675C>G p.R559G | Missense Mutation (SNP) | VAF 26/438 reads (6%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.931); catalogued as COSV58703632; called by muse, mutect2
- EFCAB7 | c.769C>G p.R257G | Missense Mutation (SNP) | VAF 95/344 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV100937695; called by muse, mutect2, varscan2
- FAM151A | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 80/552 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs112454960; called by muse, mutect2, varscan2
- FAM47C | c.2057G>A p.R686H | Missense Mutation (SNP) | VAF 45/266 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as rs145034356, COSV100792224, COSV63724689; called by muse, mutect2, varscan2
- GHRH | c.261G>T p.K87N | Missense Mutation (SNP) | VAF 68/345 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52903308; called by muse, mutect2, varscan2
- LAMC3 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs367598489; called by muse, mutect2, varscan2
- MED12 | c.1323C>A p.F441L | Missense Mutation (SNP) | VAF 27/285 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.387); catalogued as COSV100378558, COSV100380084; called by muse, mutect2, varscan2
- P2RY8 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 42/268 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV101183963; called by muse, mutect2, varscan2
- PACRG | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 63/482 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV61324394; called by muse, mutect2, varscan2
- PHB | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 37/430 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs375008157; called by muse, mutect2
- PHIP | c.3686G>C p.R1229P | Missense Mutation (SNP) | VAF 133/339 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51504150; called by muse, mutect2, varscan2
- PKD1 | c.2068G>A p.V690I | Missense Mutation (SNP) | VAF 10/406 reads (2%) | SIFT tolerated (0.46); PolyPhen benign (0.038); catalogued as rs948344824; called by muse, mutect2
- PPM1D | c.1547C>G p.S516* | Nonsense Mutation (SNP) | VAF 685/1280 reads (54%) | catalogued as rs772936724, COSV59955538, COSV59956876; called by muse, mutect2, varscan2
- RABGAP1L | c.1300A>G p.T434A | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.777); catalogued as rs985630000; called by muse, mutect2
- RELN | c.8393C>T p.P2798L | Missense Mutation (SNP) | VAF 249/644 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.211); catalogued as COSV99067084; called by muse, mutect2, varscan2
- SHISA3 | c.359G>T p.C120F | Missense Mutation (SNP) | VAF 46/365 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs569309542; called by muse, mutect2, varscan2
- TBX18 | c.1577C>G p.P526R | Missense Mutation (SNP) | VAF 107/431 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149453199, COSV63737874; called by muse, mutect2, varscan2
- USP16 | c.1847C>T p.A616V | Missense Mutation (SNP) | VAF 179/590 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1460660484; called by muse, mutect2
- XKR4 | c.607G>C p.G203R | Missense Mutation (SNP) | VAF 41/445 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.655); catalogued as COSV59304175; called by muse, mutect2
- ZC3H11B | c.2180T>C p.L727P | Missense Mutation (SNP) | VAF 103/1004 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1393927765; called by muse, mutect2
- ARHGEF11 | c.4175G>C p.G1392A | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); called by muse, mutect2
- CCDC63 | c.1640G>A p.S547N | Missense Mutation (SNP) | VAF 61/378 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP47 | c.4289T>G p.L1430R | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- CFAP58 | c.2282dup p.H763Afs*10 | Frame Shift Ins (INS) | VAF 118/509 reads (23%) | called by mutect2, pindel, varscan2
- CHTF18 | c.2200_2217del p.R734_T739del | In Frame Del (DEL) | VAF 78/143 reads (55%) | called by mutect2, pindel, varscan2
- COPB1 | c.881A>G p.D294G | Missense Mutation (SNP) | VAF 28/359 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DHX33 | c.1367C>G p.T456S | Missense Mutation (SNP) | VAF 60/317 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH7 | c.8489G>A p.G2830D | Missense Mutation (SNP) | VAF 68/395 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FAM50A | c.887T>G p.V296G | Missense Mutation (SNP) | VAF 22/542 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2
- FHOD1 | c.2336C>G p.A779G | Missense Mutation (SNP) | VAF 65/442 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- GAD1 | c.1645T>G p.S549A | Missense Mutation (SNP) | VAF 44/401 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GPX2 | c.536A>G p.E179G | Missense Mutation (SNP) | VAF 118/357 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HIPK4 | c.886G>A p.G296S | Missense Mutation (SNP) | VAF 16/515 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.029); called by muse, mutect2
- HYDIN | c.11774G>C p.C3925S | Missense Mutation (SNP) | VAF 52/209 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- JCAD | c.2890G>T p.G964* | Nonsense Mutation (SNP) | VAF 54/388 reads (14%) | called by muse, mutect2, varscan2
- KCNIP4 | c.736T>G p.F246V | Missense Mutation (SNP) | VAF 59/213 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- LAMA5 | c.3444-2A>G p.X1148_splice | Splice Site (SNP) | VAF 40/324 reads (12%) | called by muse, mutect2, varscan2
- LIPH | c.1069A>T p.N357Y | Missense Mutation (SNP) | VAF 18/452 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.287); called by muse, mutect2
- MYO18B | c.2265C>A p.N755K | Missense Mutation (SNP) | VAF 76/498 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by mutect2, varscan2
- OPLAH | c.3402C>A p.S1134R | Missense Mutation (SNP) | VAF 94/1101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- OR51D1 | c.344T>C p.F115S | Missense Mutation (SNP) | VAF 43/356 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OTOGL | c.4613T>C p.M1538T (on ENST00000547103; = p.M1529T on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2
- PCNX2 | c.5440C>G p.R1814G | Missense Mutation (SNP) | VAF 54/528 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPA2 | c.465A>C p.K155N | Missense Mutation (SNP) | VAF 117/212 reads (55%) | SIFT tolerated (0.46); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRKCH | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 32/311 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2
- PTPN7 | c.463A>C p.I155L (on ENST00000495688; = p.I194L on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/478 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.238); called by muse, mutect2
- PTPRQ | c.449G>C p.R150T (on ENST00000616559; = p.R108T on NM_001145026.2) | Missense Mutation (SNP) | VAF 19/447 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- RIMKLB | c.1079G>C p.R360P | Missense Mutation (SNP) | VAF 21/478 reads (4%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.418); called by muse, mutect2
- RRS1 | c.850G>A p.V284M | Missense Mutation (SNP) | VAF 86/1394 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.576); called by muse, mutect2
- RSRC2 | c.755A>G p.Q252R | Missense Mutation (SNP) | VAF 20/343 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.888); called by muse, mutect2
- SCML4 | c.74T>G p.V25G | Missense Mutation (SNP) | VAF 85/334 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC35G1 | c.781C>T p.L261F (on ENST00000427197 / NM_001134658.3; = p.L260F on NM_153226.4) | Missense Mutation (SNP) | VAF 33/508 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.042); called by muse, mutect2
- SPOCK3 | c.869A>T p.N290I | Missense Mutation (SNP) | VAF 205/374 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STIM2 | c.1985T>G p.M662R | Missense Mutation (SNP) | VAF 129/354 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- SV2A | c.1071C>G p.S357R | Missense Mutation (SNP) | VAF 11/334 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TMPRSS6 | c.1196+4C>T | Splice Region (SNP) | VAF 30/358 reads (8%) | called by muse, mutect2
- TSPAN8 | c.677T>C p.F226S | Missense Mutation (SNP) | VAF 8/209 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- USP16 | c.1718C>T p.S573F | Missense Mutation (SNP) | VAF 185/571 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- WDR44 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 90/343 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- ZNF17 | c.640G>C p.E214Q | Missense Mutation (SNP) | VAF 62/446 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ZNF347 | c.1199C>A p.P400H | Missense Mutation (SNP) | VAF 48/326 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ARID1A | c.129A>T p.A43= | Silent (SNP) | VAF 15/224 reads (7%) | called by muse, mutect2
- BCORL1 | c.693C>A p.V231= | Silent (SNP) | VAF 30/183 reads (16%) | catalogued as rs775690844; called by muse, mutect2, varscan2
- EFHD2 | c.690G>T p.A230= | Silent (SNP) | VAF 144/489 reads (29%) | called by muse, mutect2, varscan2
- EIF2B1 | c.444T>C p.F148= | Silent (SNP) | VAF 44/317 reads (14%) | called by muse, mutect2, varscan2
- EIF2B4 | c.636G>A p.L212= (on ENST00000347454 / NM_001034116.2; = p.L211= on NM_015636.3) | Silent (SNP) | VAF 66/969 reads (7%) | called by muse, mutect2
- FGF4 | c.600C>T p.T200= | Silent (SNP) | VAF 53/354 reads (15%) | called by muse, mutect2, varscan2
- GRM5 | c.3201C>G p.R1067= (on ENST00000305447 / NM_001143831.2; = p.R1035= on NM_000842.4) | Silent (SNP) | VAF 25/245 reads (10%) | called by muse, mutect2, varscan2
- ITPR2 | c.1878G>A p.R626= | Silent (SNP) | VAF 63/594 reads (11%) | called by muse, mutect2, varscan2
- OR2T12 | c.648T>C p.Y216= | Silent (SNP) | VAF 133/1316 reads (10%) | called by muse, mutect2, varscan2
- PCDHA1 | c.1608C>T p.S536= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as rs1554118038, COSV65372876; called by muse, mutect2, varscan2
- SCAF11 | c.186C>G p.V62= | Silent (SNP) | VAF 12/310 reads (4%) | called by muse, mutect2
- SHISA9 | c.954C>T p.A318= | Silent (SNP) | VAF 114/576 reads (20%) | called by muse, mutect2, varscan2
- SMC1B | c.2166T>A p.I722= | Silent (SNP) | VAF 32/561 reads (6%) | called by muse, mutect2
- ST6GALNAC1 | c.960C>T p.H320= | Silent (SNP) | VAF 116/871 reads (13%) | catalogued as rs770921397; called by muse, mutect2, varscan2
- SVOP | c.1410G>A p.V470= | Silent (SNP) | VAF 95/365 reads (26%) | catalogued as rs773025822; called by muse, mutect2, varscan2
- TBX18 | c.768C>G p.G256= | Silent (SNP) | VAF 166/388 reads (43%) | called by muse, mutect2, varscan2
- UBR5 | c.990T>C p.N330= | Silent (SNP) | VAF 20/656 reads (3%) | called by muse, mutect2
- USP16 | c.1920C>T p.F640= | Silent (SNP) | VAF 164/563 reads (29%) | called by muse, mutect2
- VPS35L | c.1593G>A p.K531= | Silent (SNP) | VAF 34/1086 reads (3%) | called by muse, mutect2
- C2CD6 | c.1582-3943T>C | Intron (SNP) | VAF 34/646 reads (5%) | called by muse, mutect2
- FES | c.1707+11C>A | Intron (SNP) | VAF 24/470 reads (5%) | called by muse, mutect2
- HMGCLL1 | c.-84C>T | 5'UTR (SNP) | VAF 25/66 reads (38%) | catalogued as rs1035913377; called by muse, mutect2, varscan2
- MCM10 | c.2355+9A>C | Intron (SNP) | VAF 103/338 reads (30%) | called by muse, mutect2, varscan2
- SLBP | c.*82C>G | 3'UTR (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- SPAM1 | c.*19G>A | 3'UTR (SNP) | VAF 181/682 reads (27%) | called by muse, mutect2
- TAF15 | c.641-17C>G | Intron (SNP) | VAF 86/281 reads (31%) | catalogued as rs748654007; called by muse, mutect2, varscan2
- ZNF286A | c.-102A>G | 5'UTR (SNP) | VAF 6/16 reads (38%) | called by mutect2, varscan2
